Gene-level copy-number profile of tumor specimen TCGA-VS-A9V0-01A from TCGA case TCGA-VS-A9V0, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.1 years (21,215 days).
Specimen TCGA-VS-A9V0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.e7ea41fa-a3f9-4592-92e1-fefa569b90a8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9V0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e370aba2-6d57-44b1-953a-14fabf0915e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 14,994; copy number 2: 38,915; copy number 3: 3,803; copy number 4: 1,871; copy number 5: 57; copy number 6: 26; copy number 7: 14; copy number 8: 42; copy number 10: 63; copy number 12: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9V0-01A-11D-A42N-01): tumor purity 0.78, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:163,042,557–163,192,038, 3 genes (within-gene range 0–1): PACRG-AS2, AL137182.1, PACRG-AS3.
- chr20:14,757,563–14,935,363, 3 genes: RPS10P2, MACROD2-AS1, AL138808.1.
- chr20:15,280,764–15,619,819, 3 genes: RNA5SP475, AL121584.1, ENSAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 215 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,081,316–39,487,177, 1 gene, copy number 5 (within-gene range 2–5): MACF1.
- chr1:39,304,294–39,691,485, 11 genes, copy number 5 (within-gene range 3–5): HSPE1P8, BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4.
- chr3:158,962,928–159,266,307, 1 gene, copy number 5 (within-gene range 3–5): IQCJ.
- chr8:54,191,582–54,479,963, 9 genes, copy number 5: AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7.
- chr8:54,522,799–54,523,297, 1 gene, copy number 5: SEC11B.
- chr8:94,895,767–95,116,455, 1 gene, copy number 7 (within-gene range 4–7): NDUFAF6.
- chr8:95,039,617–95,156,685, 7 genes, copy number 7: AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2.
- chr8:102,125,432–102,253,750, 5 genes, copy number 7: MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19.
- chr8:102,256,392–102,257,821, 1 gene, copy number 7: AP002907.1.
- chr17:39,546,104–39,747,291, 13 genes, copy number 12: RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr18:596,988–976,883, 21 genes, copy number 6: CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1.
- chr18:9,646,110–9,862,551, 5 genes, copy number 6 (within-gene range 4–6): LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1.
- chr18:11,326,270–11,552,847, 7 genes, copy number 5: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1.
- chr18:12,254,361–13,185,617, 27 genes, copy number 5 (within-gene range 4–5): CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3, PSMG2, CEP76, AP005482.2, AP005482.1, LINC01882, Y_RNA, PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2.
- chr19:27,638,483–32,869,767, 105 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
